Somatic mutation profile of tumor specimen TCGA-HU-A4H2-01A (aliquot TCGA-HU-A4H2-01A-11D-A25D-08) from TCGA case TCGA-HU-A4H2, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.9 years (21,496 days).
Specimen TCGA-HU-A4H2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fb42a84-f414-4d4f-88d1-180e0dfd9fdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4H2-10A (Blood Derived Normal), aliquot TCGA-HU-A4H2-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27f6a682-3cb1-45d7-9868-fa7885e4a7dd

The open-access MAF lists 182 somatic variants for this specimen: 139 protein-altering or splice-affecting, 41 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 41, Nonsense Mutation 8, 5'Flank 1, RNA 1, Frame Shift Del 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA1 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100796765, COSV64202964; called by muse, mutect2, varscan2
- ADCY8 | c.1009T>C p.F337L | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV53898538; called by muse, mutect2, varscan2
- AMY2A | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV70214325; called by muse, mutect2, varscan2
- ARHGAP36 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52264601; called by muse, mutect2, varscan2
- ARX | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66874867; called by muse, mutect2, varscan2
- ASTN2 | c.352C>A p.R118S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV57756506; called by muse, mutect2, varscan2
- ATAD2B | c.3041A>G p.K1014R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.879); catalogued as COSV53195809; called by muse, mutect2
- ATP13A5 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs368981593; called by muse, mutect2, varscan2
- ATP8B4 | c.1952A>C p.K651T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52710504; called by muse, mutect2, varscan2
- B4GALNT3 | c.445C>A p.H149N | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as COSV56750265; called by muse, mutect2, varscan2
- BET1 | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV55992671; called by muse, mutect2, varscan2
- BPIFB1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as rs373099188; called by muse, mutect2, varscan2
- C2orf49 | c.502A>G p.N168D | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.282); catalogued as COSV51527201; called by muse, mutect2, varscan2
- C4BPA | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | catalogued as COSV65535836; called by muse, mutect2, varscan2
- CACNG2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as COSV55632756; called by muse, mutect2, varscan2
- CD1C | c.590A>T p.K197M | Missense Mutation (SNP) | VAF 48/503 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63805834; called by muse, mutect2, varscan2
- CD63 | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV57676040; called by muse, mutect2, varscan2
- CNDP1 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 36/94 reads (38%) | catalogued as COSV62593280; called by muse, mutect2, varscan2
- CNTNAP2 | c.1472A>C p.K491T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV62151535; called by muse, mutect2, varscan2
- COX7B | c.41-1G>T p.X14_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100968783; called by muse, mutect2, varscan2
- CSMD3 | c.9493T>A p.L3165I (on ENST00000297405 / NM_001363185.1; = p.L2996I on NM_052900.3) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as COSV52117616; called by muse, mutect2, varscan2
- CSMD3 | c.3592T>G p.F1198V (on ENST00000297405 / NM_001363185.1; = p.F1094V on NM_052900.3) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52095771, COSV52117634; called by muse, mutect2, varscan2
- CTNNA3 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs1336450383, COSV57717549; called by muse, mutect2, varscan2
- CUBN | c.4033C>T p.R1345W | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs770413754, COSV64709315; called by muse, mutect2, varscan2
- DCAF12L2 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.144); catalogued as rs1261536454, COSV63580615, COSV63584127; called by muse, mutect2
- DCDC1 | c.45G>C p.Q15H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV60835979; called by muse, mutect2, varscan2
- DCHS1 | c.3394C>T p.R1132* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs775982308, COSV55031592; called by muse, mutect2, varscan2
- DCLK1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55175130; called by muse, mutect2, varscan2
- DNAH12 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV60855865; called by muse, mutect2, varscan2
- DNAH5 | c.9928C>T p.R3310C | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs900076362, COSV54204182; called by muse, mutect2, varscan2
- DNAH5 | c.5642C>T p.T1881M | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs190749755, COSV54205937; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK5 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV52815994, COSV52824312; called by muse, mutect2, varscan2
- DZANK1 | c.785T>C p.M262T (on ENST00000262547 / NM_001099407.1; = p.M63T on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs375255125, COSV52748285; called by muse, mutect2
- EDEM3 | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58922408; called by muse, mutect2, varscan2
- EEFSEC | c.721A>G p.M241V | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as COSV54620999; called by muse, mutect2, varscan2
- EHMT2 | c.2750G>A p.R917H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); catalogued as COSV64994795; called by muse, mutect2, varscan2
- ELL2 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV52981410; called by muse, mutect2, varscan2
- EPHA6 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.127); catalogued as COSV67561940; called by muse, mutect2
- FAH | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.08); catalogued as COSV55720395; called by muse, mutect2, varscan2
- FAM184A | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV58852170, COSV58855151; called by mutect2, varscan2
- FAM83B | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs367914924; called by muse, mutect2, varscan2
- FAT4 | c.12274A>C p.S4092R | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV58674174; called by muse, mutect2, varscan2
- FCRL1 | c.653A>G p.Q218R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV63824121; called by muse, mutect2, varscan2
- FGFR1 | c.2218G>A p.V740M (on ENST00000447712 / NM_023110.3; = p.V738M on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV58329570; called by muse, mutect2, varscan2
- FGGY | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs778553524, COSV58027566; called by muse, mutect2, varscan2
- FOXA2 | c.31G>T p.E11* (on ENST00000377115 / NM_153675.3; = p.E17* on NM_021784.5) | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as COSV65795746; called by muse, mutect2, varscan2
- FRY | c.6026G>C p.C2009S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as COSV66566254, COSV66570610; called by muse, mutect2, varscan2
- FSIP2 | c.18070A>C p.I6024L | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as COSV100553935; called by muse, mutect2, varscan2
- GABRG2 | c.180A>C p.K60N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62715881; called by muse, mutect2, varscan2
- GK2 | c.125A>C p.E42A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV62626231, COSV62628149; called by muse, mutect2, varscan2
- GPATCH8 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs201081173; called by muse, mutect2, varscan2
- GRM1 | c.2307C>A p.Y769* | Nonsense Mutation (SNP) | VAF 23/105 reads (22%) | catalogued as COSV51112495; called by muse, mutect2, varscan2
- HAVCR1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59398189; called by muse, mutect2
- HIVEP3 | c.1937A>C p.N646T | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56010740, COSV99913224; called by muse, varscan2
- IFT122 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755585099, COSV56200349; called by muse, mutect2, varscan2
- IGLV4-69 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs369206978; called by muse, mutect2, varscan2
- INKA2 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139428718, COSV61877241; called by muse, mutect2, varscan2
- INSRR | c.2936T>A p.I979N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63871290; called by muse, mutect2, varscan2
- IVL | c.447A>T p.K149N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.187); catalogued as COSV100908307, COSV64215682; called by muse, mutect2, varscan2
- JHY | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs769092607, COSV57073362; called by muse, mutect2, varscan2
- JPH2 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.388); catalogued as COSV65902078; called by muse, mutect2, varscan2
- KCNIP1 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV61081139; called by muse, mutect2, varscan2
- LCE2B | c.56A>G p.K19R | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.801); catalogued as rs751189395, COSV64227452; called by muse, mutect2, varscan2
- LEPROTL1 | c.334A>T p.T112S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV58304351; called by muse, mutect2, varscan2
- LRP12 | c.1110A>C p.Q370H | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV52626232; called by muse, mutect2, varscan2
- LRP4 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66134371; called by muse, mutect2, varscan2
- LRP5 | c.4622C>T p.T1541M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150862227, COSV53712176; called by muse, mutect2, varscan2
- LRRTM4 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101297670, COSV69139188; called by muse, mutect2, varscan2
- MAT1A | c.117T>A p.D39E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64744860; called by muse, mutect2, varscan2
- MC3R | c.826T>A p.C276S | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV54763189; called by muse, mutect2, varscan2
- MRGPRX2 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs779414608, COSV61673849; called by muse, mutect2, varscan2
- MTPN | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.934); catalogued as rs1423921992, COSV101262927, COSV67599324; called by muse, mutect2, varscan2
- MYH7 | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs202141173, HM971868, COSV62516088; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NCOR1 | c.5483C>T p.A1828V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV51963796; called by muse, mutect2, varscan2
- NPAS4 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60649133; called by muse, mutect2, varscan2
- NRXN1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs748372282, COSV68004989, COSV68005183; called by muse, mutect2, varscan2
- OR4A16 | c.17A>T p.N6I | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV59042124; called by muse, mutect2
- OR5AN1 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV58321704; called by muse, mutect2, varscan2
- OSBPL7 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772511329, COSV50107031; called by muse, mutect2, varscan2
- PCDH11X | c.3565G>A p.V1189M | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV53447862, COSV53516758; called by muse, mutect2, varscan2
- PCDH17 | c.2349G>A p.M783I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV64972304; called by muse, mutect2, varscan2
- PCDH7 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162850887, COSV62337030; called by muse, mutect2, varscan2
- PCDHB8 | c.2008C>A p.P670T | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV50755913; called by muse, mutect2, varscan2
- PDHX | c.857T>A p.V286D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57164455; called by muse, mutect2, varscan2
- PIGR | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV62903385; called by muse, mutect2, varscan2
- PLXDC2 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65901439; called by muse, mutect2, varscan2
- PRAM1 | c.696G>C p.Q232H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV55312291; called by muse, mutect2, varscan2
- PRKCG | c.805G>C p.A269P | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54724716; called by muse, mutect2, varscan2
- PRKD1 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV59559536; called by muse, mutect2, varscan2
- PRSS58 | c.267T>A p.H89Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV101616085, COSV73488465; called by muse, mutect2, varscan2
- RAB23 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs1049674573, COSV58097428; called by muse, mutect2
- RBMS2 | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); catalogued as COSV100008350; called by muse, mutect2, varscan2
- RPL10L | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs1452127228, COSV53558545; called by muse, mutect2, varscan2
- RUNDC3B | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55946404; called by muse, mutect2, varscan2
- RYR1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); catalogued as rs727504129, CM152875, COSV62091125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.1165T>G p.F389V | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56566795; called by muse, mutect2, varscan2
- SCN2A | c.1475A>C p.K492T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV51834338; called by muse, mutect2
- SCN3A | c.5063A>G p.D1688G | Missense Mutation (SNP) | VAF 126/282 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1245857364, COSV51803205; called by muse, mutect2, varscan2
- SCRN2 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765282643, COSV51635102; called by muse, mutect2, varscan2
- SDS | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV57452830; called by muse, mutect2, varscan2
- SLC9A5 | c.392A>C p.N131T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55360658; called by muse, mutect2, varscan2
- SMURF2 | c.2147G>A p.C716Y | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52313193; called by muse, mutect2, varscan2
- SOHLH2 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV58520869; called by muse, mutect2, varscan2
- SORCS3 | c.1718T>C p.L573P | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV63803879; called by muse, mutect2, varscan2
- SOX9 | c.1490_1492dup p.H497_W498insY | In Frame Ins (INS) | VAF 38/126 reads (30%) | catalogued as COSV99818466; called by mutect2, pindel, varscan2
- SPAG9 | c.1192G>A p.D398N (on ENST00000262013 / NM_001130528.3; = p.D384N on NM_003971.6) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56232170; called by muse, varscan2
- SPATA16 | c.1291A>G p.K431E | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV63527286; called by muse, mutect2, varscan2
- ST8SIA4 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | PolyPhen benign (0.006); catalogued as COSV51506903; called by muse, mutect2, varscan2
- STXBP5L | c.1564T>A p.W522R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56502898; called by muse, mutect2, varscan2
- SVEP1 | c.4990C>A p.L1664M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs1191038198, COSV65680357; called by mutect2, varscan2
- SYBU | c.1979G>A p.R660H (on ENST00000276646 / NM_001099754.2; = p.R659H on NM_017786.6) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs74885615; called by muse, mutect2, varscan2
- SYN2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs746172582, COSV70284950; called by muse, mutect2
- SYNJ2 | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV62895893; called by muse, mutect2, varscan2
- TAS2R42 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs376310818, COSV62084411; called by muse, mutect2, varscan2
- TCHH | c.3512G>A p.R1171H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as rs754428406, COSV64273254; called by muse, mutect2, varscan2
- TMC7 | c.115T>C p.F39L | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as COSV58581898; called by muse, mutect2, varscan2
- TMPO | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99701877; called by muse, mutect2, varscan2
- TMPRSS11E | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100542207; called by muse, mutect2
- TMX3 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as rs140330197, COSV100218146, COSV55184240; called by muse, mutect2, varscan2
- TNNI3K | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.98); catalogued as COSV53946136; called by muse, mutect2, varscan2
- TOPBP1 | c.3337C>T p.R1113C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751699737, COSV53433007; called by muse, mutect2, varscan2
- TOPBP1 | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53433026, COSV99605096; called by muse, mutect2
- TRPM6 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV62504076; called by muse, mutect2, varscan2
- TTN | c.17224T>C p.S5742P (on ENST00000591111; = p.S4815P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen probably damaging (0.974); catalogued as COSV59916334; called by muse, mutect2, varscan2
- UGT2A3 | c.310T>G p.W104G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52359086; called by muse, mutect2, varscan2
- UNC5B | c.2305A>G p.K769E | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV58975043; called by muse, mutect2, varscan2
- USH2A | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100228269, COSV56335742; called by muse, mutect2, varscan2
- VPS52 | c.1709T>C p.M570T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.288); catalogued as COSV71403414; called by muse, mutect2, varscan2
- XCR1 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs866621298; called by muse, mutect2
- ZAN | c.4771G>A p.G1591R | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs370638690; called by muse, mutect2, varscan2
- ZBTB16 | c.1745A>C p.K582T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV100251911, COSV60090006, COSV60099514; called by muse, mutect2, varscan2
- ZNF256 | c.1830A>T p.K610N | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1177553045, COSV56596492; called by muse, mutect2
- ZNF284 | c.715A>C p.S239R | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.32); catalogued as COSV69690731; called by muse, mutect2
- ZNF320 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 122/200 reads (61%) | SIFT tolerated (0.5); PolyPhen benign (0.063); catalogued as rs752009361, COSV67087671; called by muse, mutect2, varscan2
- ZNF609 | c.1634T>C p.L545P | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as COSV58580458; called by muse, mutect2, varscan2
- ZNF804B | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60818879; called by muse, mutect2, varscan2
- FCGBP | c.6433G>C p.A2145P | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- IGHV1-3 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- TP53 | c.453_477del p.P152Wfs*10 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.264C>T p.F88= (on ENST00000506720 / NM_001322402.2; = p.F20= on NM_015236.6) | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV72266472; called by muse, mutect2, varscan2
- ADH1B | c.336C>T p.C112= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1297724742, COSV59295384; called by muse, mutect2, varscan2
- ATM | c.5634G>A p.S1878= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs767070325, COSV53730272; ClinVar: likely benign; called by mutect2, varscan2
- C1orf127 | c.459G>A p.P153= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs1439146449, COSV65436608; called by muse, mutect2, varscan2
- CD19 | c.348G>A p.E116= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV61187968; called by muse, mutect2, varscan2
- CDHR1 | c.1050G>A p.P350= | Silent (SNP) | VAF 29/54 reads (54%) | catalogued as rs199721776, COSV60560036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST13 | c.408C>T p.R136= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1448432219, COSV60041522; called by muse, mutect2, varscan2
- COL4A5 | c.1458A>C p.G486= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV60357212, COSV60360135; called by muse, mutect2, varscan2
- FAM174A | c.84G>T p.G28= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV57062113; called by muse, mutect2, varscan2
- FCGBP | c.5616C>T p.Y1872= | Silent (SNP) | VAF 22/496 reads (4%) | catalogued as rs1388553185; called by muse, mutect2
- FOXC2 | c.1026C>T p.A342= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs755617186, COSV57443783; called by muse, mutect2, varscan2
- GALNT13 | c.829A>C p.R277= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV67211996; called by muse, mutect2, varscan2
- GPR39 | c.606C>T p.P202= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV61421600; called by muse, mutect2, varscan2
- HIVEP3 | c.1854G>A p.S618= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as rs200286795; called by muse, varscan2
- ICAM1 | c.354G>A p.L118= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs779217695, COSV53423821; called by muse, mutect2, varscan2
- IGDCC3 | c.1656C>A p.G552= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV60076725; called by muse, mutect2, varscan2
- KDF1 | c.399A>C p.G133= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100264370; called by muse, mutect2, varscan2
- KRT27 | c.840C>T p.N280= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs368841575, COSV56970931; called by muse, mutect2, varscan2
- LHFPL5 | c.111C>T p.S37= | Silent (SNP) | VAF 42/215 reads (20%) | catalogued as rs757495483, COSV64177237; called by muse, mutect2, varscan2
- LRP1 | c.6639C>T p.H2213= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs757881461, COSV54503744; called by muse, mutect2, varscan2
- NOLC1 | c.675T>C p.S225= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as rs1044073474, COSV64180046; called by muse, mutect2, varscan2
- NR0B2 | c.450A>G p.Q150= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs139159423; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR2A42 | c.366C>T p.Y122= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs746446120, COSV101195812; called by mutect2, varscan2
- PAK5 | c.1260C>A p.S420= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV62022631; called by muse, mutect2, varscan2
- PCDHA10 | c.1335C>T p.A445= | Silent (SNP) | VAF 55/236 reads (23%) | catalogued as rs781834606, COSV56482128; called by muse, mutect2, varscan2
- PCDHB14 | c.1563C>T p.Y521= | Silent (SNP) | VAF 48/222 reads (22%) | catalogued as rs1458933245, COSV53386933; called by muse, mutect2, varscan2
- PDIA2 | c.570C>T p.F190= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV51984155; called by muse, mutect2, varscan2
- RAG2 | c.153G>A p.K51= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs772223078, COSV57556582, COSV57556650; called by muse, mutect2, varscan2
- RENBP | c.621G>A p.E207= | Silent (SNP) | VAF 46/209 reads (22%) | catalogued as COSV60069882; called by muse, mutect2, varscan2
- RGS7BP | c.435G>T p.L145= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs747267722, COSV61833761; called by muse, mutect2, varscan2
- SAMD9L | c.3672C>A p.S1224= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs775860375, COSV59080060; called by muse, mutect2, varscan2
- SGK2 | c.312G>A p.G104= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as rs943590059, COSV58312340; called by muse, mutect2, varscan2
- SI | c.1719T>C p.A573= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV52268589; called by muse, mutect2, varscan2
- SLC12A5 | c.2568C>T p.H856= (on ENST00000454036 / NM_001134771.2; = p.H833= on NM_020708.5) | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as rs371925559; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC46A2 | c.417G>A p.A139= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs1435394793, COSV65289689; called by muse, mutect2, varscan2
- TRPA1 | c.1563G>A p.A521= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs369662285; called by muse, mutect2, varscan2
- TRPM6 | c.2247A>T p.I749= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV62504066; called by muse, mutect2, varscan2
- ZFR2 | c.213C>A p.G71= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99506958; called by muse, mutect2, varscan2
- ZFYVE9 | c.4173T>C p.D1391= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as rs1318073368, COSV55090756; called by muse, mutect2, varscan2
- ZNF142 | c.2169G>T p.R723= (on ENST00000411696 / NM_001379660.1; = p.R523= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs894496210, COSV68743096; called by muse, mutect2, varscan2
- ZNF804B | c.2763C>A p.T921= | Silent (SNP) | VAF 32/336 reads (10%) | catalogued as COSV60818887, COSV60826727; called by muse, mutect2
- FOLH1B | n.2027T>G | RNA (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- RNU6-104P | chr8:43300575 del T | 5'Flank (DEL) | VAF 15/89 reads (17%) | called by mutect2, pindel, varscan2
